Somatic mutation profile of tumor specimen 0DLHP1 from CCDI case PBBZFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,485 days).
Specimen 0DLHP1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 258ef82f-fb38-4a63-9075-526441ea1c68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b1179d0-8755-4f23-b509-aad02ddcc552

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Missense Mutation 4, Intron 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE5 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 149/422 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1041295115, COSV55197131; called by muse, mutect2, varscan2
- MYH14 | c.3556C>T p.R1186W | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1260873967, COSV51831690; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by mutect2, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 22/232 reads (9%) | called by muse, varscan2
- TAX1BP1 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 27/762 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 18/116 reads (16%) | called by muse, varscan2
- ARHGEF12 | c.3532+91T>C | Intron (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.3532+92G>A | Intron (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 36/714 reads (5%) | called by muse, mutect2
- CPLANE1 | c.*3595C>T | 3'UTR (SNP) | VAF 28/662 reads (4%) | called by muse, mutect2
- GDPD1 | c.*1327T>C | 3'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as rs1184567004, COSV104370270; called by muse, mutect2
- LRRC8B | c.*74A>G | 3'UTR (SNP) | VAF 9/81 reads (11%) | catalogued as rs891944719, COSV58375831; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 19/179 reads (11%) | called by muse, varscan2
